Somatic mutation profile of tumor specimen TCGA-DB-A64W-01A (aliquot TCGA-DB-A64W-01A-11D-A29Q-08) from TCGA case TCGA-DB-A64W, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 65.5 years (23,936 days).
Specimen TCGA-DB-A64W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be4d0bbd-75cc-4821-b223-3764bbbb5051.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A64W-10A (Blood Derived Normal), aliquot TCGA-DB-A64W-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80346d93-3d9a-49b6-a5cb-7abc8def44f3

The open-access MAF lists 47 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 31, Silent 10, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs896110034, COSV54951846, COSV54957798; called by muse, mutect2, varscan2
- ADGRV1 | c.5312A>G p.Q1771R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.837); catalogued as COSV67980765; called by muse, mutect2
- AFF2 | c.3689A>G p.N1230S | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.446); catalogued as COSV53981317; called by muse, mutect2, varscan2
- AGPAT2 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1564291266, COSV58247224; called by muse, mutect2, varscan2
- ASMTL | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs774064974, COSV67243187; called by muse, mutect2, varscan2
- CIC | c.703G>T p.G235C | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50552133; called by muse, mutect2, varscan2
- CLEC14A | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.007); catalogued as COSV60562032; called by muse, mutect2, varscan2
- DENND2D | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV62958709; called by muse, mutect2, varscan2
- DOCK4 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70234492; called by muse, mutect2
- GK | c.1475G>A p.R492Q (on ENST00000427190 / NM_001205019.2; = p.R486Q on NM_000167.6) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs747731781, COSV66732101; called by muse, mutect2, varscan2
- IGSF10 | c.4868A>G p.K1623R | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV56782823, COSV56784938; called by muse, mutect2, varscan2
- KLF5 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs778424957, COSV66613869; called by muse, mutect2, varscan2
- MCPH1 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.17); catalogued as rs768537043, COSV60911428; called by muse, mutect2, varscan2
- MMP9 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748513980, COSV63433863; called by muse, mutect2, varscan2
- NEURL4 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs369191676; called by muse, mutect2, varscan2
- NHS | c.2641G>T p.E881* | Nonsense Mutation (SNP) | VAF 70/149 reads (47%) | catalogued as COSV66272747; called by muse, mutect2, varscan2
- OR6N2 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59410723; called by muse, mutect2, varscan2
- PBDC1 | c.557A>T p.N186I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV64895664; called by muse, mutect2, varscan2
- PCDHGC3 | c.2086C>A p.L696I | Missense Mutation (SNP) | VAF 204/478 reads (43%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.723); catalogued as COSV52746700; called by muse, mutect2, varscan2
- PDE6C | c.2536G>A p.G846S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV63271225; called by muse, mutect2, varscan2
- PDILT | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 33/68 reads (49%) | catalogued as rs139247719, COSV56700444; called by muse, mutect2, varscan2
- PRKAR1A | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CD093320, COSV56836025; called by muse, mutect2, varscan2
- PRSS57 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.153); catalogued as rs771932256, COSV61385446; called by muse, mutect2, varscan2
- RBMXL1 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 122/167 reads (73%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.613); catalogued as rs764148399, COSV53099432, COSV53104180; called by muse, varscan2
- SEZ6L2 | c.1910A>C p.E637A (on ENST00000308713 / NM_001114099.3; = p.E567A on NM_012410.4) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58098041; called by muse, mutect2, varscan2
- SKAP2 | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV61722113; called by muse, mutect2, varscan2
- SMCHD1 | c.3161A>G p.H1054R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV55253268; called by muse, mutect2, varscan2
- TELO2 | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs767256385, COSV51976566; called by muse, mutect2, varscan2
- TRO | c.4234A>T p.T1412S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.931); catalogued as COSV51499382; called by muse, mutect2, varscan2
- TSNAXIP1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs779520933, COSV54648614; called by muse, mutect2, varscan2
- ZBTB11 | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 31/71 reads (44%) | catalogued as rs763698199, COSV57244373; called by muse, mutect2, varscan2
- ZBTB20 | c.1949A>G p.N650S (on ENST00000474710 / NM_001164342.2; = p.N577S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV61842535; called by muse, mutect2, varscan2
- BCOR | c.3172del p.Q1058Rfs*55 | Frame Shift Del (DEL) | VAF 36/101 reads (36%) | called by mutect2, pindel, varscan2
- ZCCHC10 | c.408dup p.E137Rfs*4 (on ENST00000509437 / NM_001300818.3; = p.E115Rfs*4 on NM_017665.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- ZNF292 | c.1158dup p.R387Tfs*7 | Frame Shift Ins (INS) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- ADARB2 | c.996G>A p.A332= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV67218139; called by muse, mutect2, varscan2
- ATXN2L | c.3036A>G p.A1012= | Silent (SNP) | VAF 68/173 reads (39%) | catalogued as COSV57367601; called by muse, mutect2, varscan2
- EPRS1 | c.4425A>T p.G1475= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV65097688; called by muse, mutect2, varscan2
- EZR | c.1479C>T p.G493= | Silent (SNP) | VAF 50/153 reads (33%) | catalogued as rs201524101; called by muse, mutect2, varscan2
- HECW1 | c.1095G>A p.Q365= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs763007524, COSV67825368; called by muse, mutect2, varscan2
- OR52B4 | c.585A>G p.R195= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV68768694; called by muse, mutect2, varscan2
- PRF1 | c.645T>G p.L215= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV64614540; called by muse, mutect2, varscan2
- SDS | c.972T>C p.N324= | Silent (SNP) | VAF 161/369 reads (44%) | catalogued as COSV55106004; called by muse, mutect2, varscan2
- USP26 | c.2670A>G p.E890= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV63708246; called by muse, mutect2, varscan2
- WNK2 | c.2067C>T p.P689= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs372392898, COSV52936882; called by muse, mutect2, varscan2
